Somatic mutation profile of tumor specimen ALCH-B34T-TTP1-A (aliquot ALCH-B34T-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B34T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.0 years (28,865 days).
Specimen ALCH-B34T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2061cd90-0bbb-462a-a447-a318ef0a2ea6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34T-NB1-A (Blood Derived Normal), aliquot ALCH-B34T-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1230db90-7870-4143-adbd-f3153bbb510b

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 99/641 reads (15%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, pindel
- FLAD1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 14/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99423283; called by muse, mutect2
- MYT1 | c.2675+4C>T | Splice Region (SNP) | VAF 14/336 reads (4%) | catalogued as rs780792496; called by muse, mutect2
- AL645922.1 | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 18/687 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.445); called by muse, mutect2
- TBL3 | c.2201T>A p.V734E | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CLEC14A | c.255G>A p.G85= | Silent (SNP) | VAF 54/283 reads (19%) | called by muse, mutect2, varscan2
- MYLK2 | c.738C>G p.L246= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV65659383; called by muse, mutect2
- SLC1A5 | c.210G>A p.L70= | Silent (SNP) | VAF 21/554 reads (4%) | called by muse, mutect2
- TTC30B | c.549C>T p.A183= | Silent (SNP) | VAF 19/454 reads (4%) | called by muse, mutect2
